Gene-level copy-number profile of tumor specimen HCM-BROD-0103-C71-01A from HCMI case HCM-BROD-0103-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,295 days).
Specimen HCM-BROD-0103-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file be126fb4-d31f-4064-a32f-748bc1d82ccc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0103-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,377 have no estimate.
https://portal.gdc.cancer.gov/files/e2108916-a28e-4b59-b84e-c4a6171ae1ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,216; copy number 2: 51,436; copy number 3: 519; copy number 4: 69; copy number 5: 4; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:22,609,228–22,690,665, 2 genes, copy number 6 (within-gene range 1–6): AC087241.2, ETNK1.
- chr12:24,212,421–24,584,549, 4 genes, copy number 5: MIR920, SOX5-AS1, LINC00477, KNOP1P1.

Autosomal genes at a single copy (total copy number 1): 6,216. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
